Somatic mutation profile of tumor specimen C3L-06413-02 (aliquot CPT0393250006) from CPTAC case C3L-06413, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 84.1 years (30,703 days).
Specimen C3L-06413-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5e63245-4e68-47a1-96e7-ac8803736baf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06413-31 (Blood Derived Normal), aliquot CPT0390670004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb205e71-3500-402c-b183-d53418df17c8

The open-access MAF lists 305 somatic variants for this specimen: 233 protein-altering or splice-affecting, 66 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 66, Nonsense Mutation 12, Frame Shift Ins 6, Splice Site 3, Intron 3, Frame Shift Del 3, Splice Region 2, 3'UTR 1, RNA 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NIPAL4 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 73/398 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370356566, CM074276; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 82/389 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 216/433 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2557A>C p.T853P | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1448293204, COSV100229382; called by mutect2, varscan2
- ABCA12 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 81/370 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs868778584, COSV55948598; called by muse, mutect2, varscan2
- ACOT11 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 65/485 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs747945837, COSV56366602; called by muse, mutect2, varscan2
- ACSS1 | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 90/515 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs1272396085; called by muse, mutect2, varscan2
- ACTA1 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100796765, COSV64202964; called by muse, mutect2, varscan2
- ADCY8 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 432/818 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs770975076; called by muse, varscan2
- ADGRB3 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 167/405 reads (41%) | catalogued as rs752634970, COSV65397795; called by muse, mutect2, varscan2
- ANKRD18A | c.2123A>C p.K708T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV101294923, COSV68802667; called by muse, mutect2, varscan2
- ANKRD30A | c.1927G>C p.E643Q (on ENST00000611781; = p.E587Q on NM_052997.2) | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs376283553; called by muse, mutect2, varscan2
- ASCC3 | c.3404C>A p.P1135Q | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV100226140; called by muse, mutect2, varscan2
- ATP13A2 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 77/370 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs142720276; called by muse, mutect2, varscan2
- ATP6V1E2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 34/763 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs934734612; called by muse, mutect2
- BRINP1 | c.1705G>A p.G569R | Missense Mutation (SNP) | VAF 87/498 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748260709; called by muse, mutect2, varscan2
- C9orf50 | c.1251C>G p.Y417* | Nonsense Mutation (SNP) | VAF 86/556 reads (15%) | catalogued as COSV65252905; called by muse, mutect2, varscan2
- CACNA2D3 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 76/465 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs772601031, COSV55554973; called by muse, varscan2
- CCDC178 | c.633A>T p.Q211H | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100287735, COSV55757125; called by muse, mutect2, varscan2
- CFHR4 | c.1607A>C p.K536T (on ENST00000367416 / NM_001201551.2; = p.K290T on NM_006684.5) | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV52227348; called by muse, mutect2, varscan2
- CHGB | c.1975T>G p.L659V | Missense Mutation (SNP) | VAF 35/403 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66760144; called by muse, mutect2
- CNTN1 | c.2194A>T p.R732* | Nonsense Mutation (SNP) | VAF 44/288 reads (15%) | catalogued as COSV100751878; called by muse, mutect2, varscan2
- CNTN5 | c.1274A>T p.K425M | Missense Mutation (SNP) | VAF 91/445 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV54305606; called by muse, mutect2, varscan2
- COL21A1 | c.1860A>G p.G620= | Splice Region (SNP) | VAF 64/416 reads (15%) | catalogued as COSV55167684; called by muse, mutect2, varscan2
- CRISPLD1 | c.281G>C p.R94T | Missense Mutation (SNP) | VAF 147/570 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51553228; called by muse, mutect2, varscan2
- CYP4A22 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 135/930 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs777531624; called by muse, mutect2, varscan2
- DNAH2 | c.12002T>A p.L4001H | Missense Mutation (SNP) | VAF 163/444 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483507973; called by muse, mutect2, varscan2
- DOCK10 | c.6555A>C p.E2185D | Missense Mutation (SNP) | VAF 66/251 reads (26%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99292414; called by muse, mutect2, varscan2
- EIF6 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 119/644 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs758837850; called by muse, mutect2, varscan2
- FAM135B | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 115/778 reads (15%) | catalogued as COSV99417328; called by muse, mutect2, varscan2
- FAM50A | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 98/234 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV50131410; called by muse, mutect2, varscan2
- FBXL2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 133/382 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs774933477, COSV52139667; called by muse, mutect2, varscan2
- FER1L6 | c.5032A>G p.I1678V | Missense Mutation (SNP) | VAF 358/631 reads (57%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as rs765803244; called by muse, mutect2, varscan2
- FLRT2 | c.1362G>T p.W454C | Missense Mutation (SNP) | VAF 74/477 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58140775; called by mutect2, varscan2
- GNG11 | c.201A>C p.K67N | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50350433; called by muse, mutect2, varscan2
- GPC6 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 98/557 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs376951709, COSV65516774; called by muse, mutect2, varscan2
- GPR78 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 169/561 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs752244272; called by muse, mutect2, varscan2
- HERC4 | c.2399T>G p.V800G (on ENST00000395198 / NM_022079.3; = p.V792G on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53274991; called by muse, mutect2
- HK3 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 85/360 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.088); catalogued as rs866293926, COSV52844513; called by muse, mutect2, varscan2
- HS6ST2 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 108/290 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1287608029; called by muse, mutect2, varscan2
- IGSF9 | c.2644C>T p.R882W (on ENST00000368094 / NM_001135050.2; = p.R866W on NM_020789.4) | Missense Mutation (SNP) | VAF 191/831 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs534654530; called by muse, mutect2, varscan2
- IL20RB | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 57/296 reads (19%) | catalogued as rs1314496146; called by muse, mutect2, varscan2
- INSM2 | c.1605T>A p.F535L | Missense Mutation (SNP) | VAF 24/792 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV51877107; called by muse, mutect2
- KCNK17 | c.418G>C p.G140R | Missense Mutation (SNP) | VAF 381/699 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64684921; called by muse, mutect2, varscan2
- KRT73 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59837847; called by muse, mutect2, varscan2
- KRT81 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 94/662 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs377419026; called by mutect2, varscan2
- KRTAP2-2 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 26/373 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs12941480; called by muse, mutect2, varscan2
- LRCH4 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 86/463 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs539637465; called by muse, mutect2, varscan2
- LRRC37B | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 89/462 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs537667819; called by muse, mutect2, varscan2
- LRRC3B | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 94/503 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.042); catalogued as COSV67522081; called by muse, mutect2, varscan2
- MAGEB5 | c.761A>C p.N254T | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.06); catalogued as COSV100983456; called by muse, mutect2, varscan2
- MAGEC1 | c.3098A>G p.E1033G | Missense Mutation (SNP) | VAF 23/295 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53581790; called by muse, mutect2
- MALRD1 | c.5493A>C p.E1831D | Missense Mutation (SNP) | VAF 49/349 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.047); catalogued as COSV104426014; called by muse, mutect2, varscan2
- MEGF8 | c.8444G>A p.G2815E (on ENST00000251268 / NM_001271938.2; = p.G2748E on NM_001410.3) | Missense Mutation (SNP) | VAF 136/616 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1326347816; called by muse, mutect2, varscan2
- MPP7 | c.412A>C p.K138Q | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556013394, COSV61730790; called by muse, mutect2, varscan2
- MYH1 | c.5584C>T p.R1862C | Missense Mutation (SNP) | VAF 129/419 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs201454258, COSV99875262; called by muse, mutect2, varscan2
- MYO16 | c.5541C>A p.N1847K | Missense Mutation (SNP) | VAF 94/544 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV62745736; called by muse, mutect2, varscan2
- NCKIPSD | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 170/486 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as rs146581696; called by muse, mutect2, varscan2
- OR10A5 | c.781T>C p.F261L | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.253); catalogued as COSV55055216; called by muse, mutect2, varscan2
- OR1D2 | c.585T>G p.N195K | Missense Mutation (SNP) | VAF 82/457 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100513953; called by muse, mutect2, varscan2
- OR52J3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 159/474 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs754756527, COSV66746561; called by muse, mutect2, varscan2
- OR5D16 | c.91T>C p.F31L | Missense Mutation (SNP) | VAF 89/588 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs752878580, COSV65722785; called by muse, mutect2, varscan2
- OR5H6 | c.535T>A p.S179T (on ENST00000642105; = p.S163T on NM_001005479.2) | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV67352104; called by muse, mutect2, varscan2
- OR5M1 | c.199T>A p.S67T | Missense Mutation (SNP) | VAF 87/672 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV101591559, COSV73202120; called by muse, mutect2, varscan2
- PAH | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs199475619, CM010948, COSV61017017; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- PCSK6 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 66/376 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs374241841; called by muse, varscan2
- PDE1B | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 71/465 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs145391059; called by muse, mutect2, varscan2
- PLCG1 | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 111/595 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.35); catalogued as COSV99718773; called by muse, mutect2, varscan2
- PLXDC2 | c.431A>C p.K144T | Missense Mutation (SNP) | VAF 80/410 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV65900424; called by muse, mutect2, varscan2
- POFUT1 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 68/435 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs769388652, COSV65260157; called by muse, mutect2, varscan2
- POTEJ | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 68/604 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs775579011; called by muse, mutect2, varscan2
- PRKACG | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 145/723 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99598462; called by muse, mutect2, varscan2
- PSG6 | c.555C>A p.N185K | Missense Mutation (SNP) | VAF 94/440 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs745681258; called by mutect2, varscan2
- PTPN23 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 96/549 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1222031507; called by muse, mutect2, varscan2
- RIMS1 | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 92/497 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.484); catalogued as rs1419274863; called by muse, mutect2, varscan2
- RIMS2 | c.1199G>T p.R400L (on ENST00000666250 / NM_001348490.2; = p.R208L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/663 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51669256, COSV51723221; called by muse, mutect2, varscan2
- SCN5A | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 122/683 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs45609733, CM055524, COSV61121574; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- SGCG | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 177/447 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747549369, COSV54570335, COSV99523342; called by muse, mutect2, varscan2
- SHROOM3 | c.3344G>A p.R1115H | Missense Mutation (SNP) | VAF 158/676 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs751952435; called by muse, mutect2, varscan2
- SIAE | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 76/558 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs201750697, COSV99703894; called by muse, mutect2, varscan2
- SKOR1 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 98/620 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.086); catalogued as rs780509897; called by muse, mutect2, varscan2
- SLC1A2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 100/600 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374504230; called by muse, mutect2, varscan2
- SLC25A14 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 91/214 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV54419536; called by muse, mutect2, varscan2
- SLITRK6 | c.120A>C p.K40N | Missense Mutation (SNP) | VAF 86/484 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68389739; called by muse, mutect2, varscan2
- SPON1 | c.606C>A p.C202* | Nonsense Mutation (SNP) | VAF 119/423 reads (28%) | catalogued as COSV59964332; called by mutect2, varscan2
- SPTA1 | c.5197T>G p.L1733V | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.739); catalogued as COSV63749514, COSV63749741; called by muse, mutect2, varscan2
- SYDE1 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 288/615 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs376129355; called by muse, mutect2, varscan2
- SYT3 | c.290G>C p.R97P | Missense Mutation (SNP) | VAF 125/617 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58896328; called by muse, mutect2, varscan2
- TMEM168 | c.520G>C p.V174L | Missense Mutation (SNP) | VAF 114/509 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV57181880; called by muse, mutect2, varscan2
- TNFRSF18 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 89/441 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs1271110528, COSV100148848, COSV100148938; called by muse, mutect2, varscan2
- TNN | c.2093A>C p.K698T | Missense Mutation (SNP) | VAF 46/404 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV53425748; called by muse, mutect2, varscan2
- TRIM49C | c.1124A>C p.E375A | Missense Mutation (SNP) | VAF 80/414 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.582); catalogued as rs570297; called by muse, mutect2, varscan2
- TRPC7 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 79/498 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755662783, COSV61452874; called by muse, mutect2, varscan2
- TTN | c.51731C>G p.P17244R (on ENST00000591111; = p.P9820R on NM_003319.4) | Missense Mutation (SNP) | VAF 76/353 reads (22%) | PolyPhen probably damaging (0.999); catalogued as rs780890752; called by muse, mutect2, varscan2
- TTN | c.44112A>C p.E14704D (on ENST00000591111; = p.E7280D on NM_003319.4) | Missense Mutation (SNP) | VAF 77/410 reads (19%) | PolyPhen benign (0.019); catalogued as COSV59947170; called by muse, mutect2, varscan2
- TTN | c.29876C>G p.S9959C (on ENST00000591111; = p.S9032C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/171 reads (17%) | PolyPhen probably damaging (0.992); catalogued as rs1393092515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.12618A>C p.E4206D (on ENST00000591111; = p.E4160D on NM_003319.4) | Missense Mutation (SNP) | VAF 16/495 reads (3%) | catalogued as COSV60003557, COSV60326324; called by muse, mutect2
- UBQLN3 | c.1864C>A p.Q622K | Missense Mutation (SNP) | VAF 167/507 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV61163616; called by muse, mutect2
- UPK1B | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 83/445 reads (19%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.996); catalogued as rs759632026, COSV51768059; called by muse, mutect2, varscan2
- USH2A | c.3463A>C p.S1155R | Missense Mutation (SNP) | VAF 71/541 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as rs766609270, COSV56372284; called by muse, mutect2, varscan2
- USP29 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 72/394 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs546426655; called by muse, mutect2, varscan2
- USP31 | c.3221G>A p.R1074H | Missense Mutation (SNP) | VAF 88/653 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.7); catalogued as rs114633724; called by muse, mutect2, varscan2
- VPS50 | c.2825C>G p.S942C | Missense Mutation (SNP) | VAF 76/351 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.726); catalogued as COSV59918679; called by muse, mutect2, varscan2
- WDR97 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 459/844 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs1044715808; called by muse, mutect2, varscan2
- XIRP2 | c.2285T>A p.L762H (on ENST00000628543; = p.L937H on NM_152381.6) | Missense Mutation (SNP) | VAF 60/399 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54689020; called by muse, mutect2, varscan2
- ZFHX4 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 139/527 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50645080; called by muse, mutect2, varscan2
- ZNF208 | c.3758A>G p.Y1253C | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs889097700, COSV68103633; called by muse, mutect2, varscan2
- ZNF658 | c.334A>T p.S112C | Missense Mutation (SNP) | VAF 79/290 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs764279607; called by muse, mutect2, varscan2
- ZNF691 | c.85-1G>C p.X29_splice | Splice Site (SNP) | VAF 80/473 reads (17%) | catalogued as COSV100996112; called by muse, mutect2, varscan2
- ADGRV1 | c.13696C>A p.L4566M | Missense Mutation (SNP) | VAF 95/406 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- AFF2 | c.1604A>C p.N535T | Missense Mutation (SNP) | VAF 125/241 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ANGPT1 | c.1079A>G p.E360G | Missense Mutation (SNP) | VAF 133/534 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANK2 | c.8707A>G p.R2903G | Missense Mutation (SNP) | VAF 81/356 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ANKRD18A | c.1652T>A p.L551H | Missense Mutation (SNP) | VAF 82/474 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APEX1 | c.299C>G p.S100* | Nonsense Mutation (SNP) | VAF 172/548 reads (31%) | called by muse, mutect2, varscan2
- ASH1L | c.3966C>G p.I1322M | Missense Mutation (SNP) | VAF 12/416 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- CACNA1G | c.4673A>C p.K1558T | Missense Mutation (SNP) | VAF 79/354 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CARD18 | c.37T>G p.F13V | Missense Mutation (SNP) | VAF 76/444 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CLCN1 | c.2509-27_2514del p.X837_splice | Splice Site (DEL) | VAF 66/428 reads (15%) | called by mutect2, pindel
- CLEC1A | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 61/361 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLIC6 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 144/564 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CLPTM1L | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 248/802 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CLSPN | c.88A>C p.S30R | Missense Mutation (SNP) | VAF 176/638 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CMKLR1 | c.440C>A p.S147Y (on ENST00000312143 / NM_001142344.2; = p.S145Y on NM_004072.3) | Missense Mutation (SNP) | VAF 96/660 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COG4 | c.1299G>T p.R433S | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CSF3R | c.1977G>A p.W659* | Nonsense Mutation (SNP) | VAF 98/703 reads (14%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2435G>C p.G812A | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CYP11B1 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 241/995 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CYRIA | c.35T>C p.I12T | Missense Mutation (SNP) | VAF 51/357 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DDX10 | c.173A>C p.Q58P | Missense Mutation (SNP) | VAF 62/375 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- DNAH2 | c.3368A>G p.E1123G | Missense Mutation (SNP) | VAF 71/447 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DTX3L | c.263C>G p.P88R | Missense Mutation (SNP) | VAF 84/544 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ECD | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 99/528 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- EEA1 | c.2985A>T p.K995N | Missense Mutation (SNP) | VAF 71/407 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- EGFLAM | c.1188_1192dup p.T398Mfs*2 | Frame Shift Ins (INS) | VAF 46/235 reads (20%) | called by mutect2, pindel, varscan2
- ELAVL4 | c.1041C>A p.N347K | Missense Mutation (SNP) | VAF 77/615 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ERICH6 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 69/430 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ETV6 | c.928del p.E310Kfs*6 | Frame Shift Del (DEL) | VAF 189/654 reads (29%) | called by mutect2, pindel, varscan2
- EXOC3L2 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 140/670 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FAM120A | c.1817G>C p.R606P | Missense Mutation (SNP) | VAF 99/622 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FASTK | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 76/403 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FCRLB | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 120/660 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- FHIT | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 166/521 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- FSCB | c.575C>A p.A192D | Missense Mutation (SNP) | VAF 98/575 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- FZD8 | c.1357T>C p.S453P | Missense Mutation (SNP) | VAF 108/701 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GAS6 | c.1034G>A p.W345* | Nonsense Mutation (SNP) | VAF 96/782 reads (12%) | called by muse, mutect2, varscan2
- GPATCH2L | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 87/480 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- GRID2 | c.2192A>C p.K731T | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- GUCY1A1 | c.2015A>C p.K672T | Missense Mutation (SNP) | VAF 65/371 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GUCY2D | c.462G>A p.W154* | Nonsense Mutation (SNP) | VAF 160/867 reads (18%) | called by muse, mutect2, varscan2
- HCRTR2 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 30/580 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- HECTD4 | c.1044del p.N349Tfs*58 | Frame Shift Del (DEL) | VAF 147/478 reads (31%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.7475G>C p.S2492T | Missense Mutation (SNP) | VAF 205/557 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- HSPB7 | c.509T>G p.I170S | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- IFI16 | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 54/313 reads (17%) | called by muse, mutect2, varscan2
- IL36RN | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 76/479 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNA4 | c.1045G>T p.G349W | Missense Mutation (SNP) | VAF 73/582 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- KCNJ12 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 114/895 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KRTAP2-1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 58/1022 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- LRFN5 | c.1438A>C p.T480P | Missense Mutation (SNP) | VAF 68/464 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- LRRC7 | c.1921G>A p.A641T (on ENST00000651989 / NM_001370785.2; = p.A608T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/692 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LRRC7 | c.3755A>G p.Q1252R (on ENST00000651989 / NM_001370785.2; = p.Q1219R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/484 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LRRC9 | c.1365G>T p.E455D | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC9 | c.1634G>C p.R545T | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- LYST | c.8366C>A p.A2789D | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MAGEB16 | c.789G>C p.Q263H | Missense Mutation (SNP) | VAF 113/277 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MAGEC1 | c.2912A>C p.D971A | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2
- MAP2K7 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 243/437 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MB21D2 | c.1073del p.L358Cfs*67 | Frame Shift Del (DEL) | VAF 103/676 reads (15%) | called by mutect2, pindel, varscan2
- MIXL1 | c.387G>C p.R129S | Missense Mutation (SNP) | VAF 84/482 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MMS22L | c.2242T>A p.L748M | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- MNDA | c.986A>C p.K329T | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MPP5 | c.18G>T p.M6I | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by mutect2, varscan2
- MPP5 | c.19A>T p.N7Y | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MS4A2 | c.651dup p.V218Cfs*3 | Frame Shift Ins (INS) | VAF 47/277 reads (17%) | called by mutect2, pindel, varscan2
- MYH8 | c.4888A>G p.I1630V | Missense Mutation (SNP) | VAF 210/566 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, varscan2
- MYH9 | c.4580A>G p.K1527R | Missense Mutation (SNP) | VAF 160/404 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- NALCN | c.825G>T p.E275D | Missense Mutation (SNP) | VAF 168/487 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- NCR1 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 131/725 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- NID2 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 219/657 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NKRF | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 105/282 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPY5R | c.889T>G p.L297V | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSD1 | c.1330C>G p.P444A | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- OR14J1 | c.947A>C p.K316T | Missense Mutation (SNP) | VAF 55/438 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- OR2B6 | c.182T>C p.F61S | Missense Mutation (SNP) | VAF 87/522 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- OR4S2 | c.404A>T p.N135I | Missense Mutation (SNP) | VAF 120/639 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- OR51B6 | c.653T>G p.L218W | Missense Mutation (SNP) | VAF 98/564 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR8H1 | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 146/790 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- PAPPA2 | c.3798A>C p.K1266N | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PCCA | c.2091T>A p.N697K | Missense Mutation (SNP) | VAF 77/371 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA1 | c.1514T>C p.L505P | Missense Mutation (SNP) | VAF 107/526 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PDE10A | c.2163A>C p.E721D | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PFKFB2 | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 123/607 reads (20%) | PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PHKA1 | c.1328C>G p.S443C | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PLEKHA3 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 47/386 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by mutect2, varscan2
- PLXNB2 | c.2929_2931del p.F977del | In Frame Del (DEL) | VAF 245/550 reads (45%) | called by pindel, varscan2
- POSTN | c.1566dup p.E523Rfs*17 | Frame Shift Ins (INS) | VAF 71/411 reads (17%) | called by mutect2, pindel, varscan2
- POTEI | c.71T>G p.M24R | Missense Mutation (SNP) | VAF 47/576 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); called by muse, varscan2
- PRKAA2 | c.519T>G p.S173R | Missense Mutation (SNP) | VAF 152/522 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHOT1 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- RP1 | c.4441A>G p.T1481A | Missense Mutation (SNP) | VAF 107/374 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RPRD1B | c.802dup p.V268Gfs*59 | Frame Shift Ins (INS) | VAF 91/493 reads (18%) | called by mutect2, pindel, varscan2
- SACS | c.10550T>G p.L3517R | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SBF1 | c.1152G>T p.W384C | Missense Mutation (SNP) | VAF 170/385 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SCN5A | c.3973A>G p.N1325D (on ENST00000333535 / NM_198056.3; = p.N1324D on NM_000335.5) | Missense Mutation (SNP) | VAF 71/468 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- SDC3 | c.870G>C p.Q290H | Missense Mutation (SNP) | VAF 66/467 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- SEL1L2 | c.640A>C p.N214H | Missense Mutation (SNP) | VAF 56/319 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- SHANK3 | c.1978A>G p.K660E | Missense Mutation (SNP) | VAF 86/386 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- SLC24A2 | c.430T>C p.Y144H | Missense Mutation (SNP) | VAF 96/564 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC27A6 | c.1136C>A p.A379E | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by mutect2, varscan2
- SLCO1B3 | c.2088A>C p.Q696H | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SPEF2 | c.1085T>C p.L362S | Missense Mutation (SNP) | VAF 222/571 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SPTA1 | c.2360A>G p.K787R | Missense Mutation (SNP) | VAF 92/590 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SULF2 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 94/573 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TAF6 | c.-59G>C | Splice Region (SNP) | VAF 132/622 reads (21%) | called by muse, mutect2, varscan2
- TASOR | c.1748A>G p.D583G (on ENST00000355628 / NM_001365636.2; = p.D187G on NM_015224.3) | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM132C | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 56/466 reads (12%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- TMEM225B | c.133dup p.S45Ffs*11 | Frame Shift Ins (INS) | VAF 132/609 reads (22%) | called by mutect2, pindel, varscan2
- TNRC6A | c.5122G>A p.V1708I | Missense Mutation (SNP) | VAF 95/508 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TTC28 | c.4366C>T p.P1456S | Missense Mutation (SNP) | VAF 98/459 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.55493A>C p.K18498T (on ENST00000591111; = p.K11074T on NM_003319.4) | Missense Mutation (SNP) | VAF 81/563 reads (14%) | PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- TTN | c.38990A>T p.K12997M (on ENST00000591111; = p.K5573M on NM_003319.4) | Missense Mutation (SNP) | VAF 106/576 reads (18%) | PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- UGT3A2 | c.768T>G p.D256E | Missense Mutation (SNP) | VAF 82/647 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- UNC13C | c.3290C>T p.P1097L | Missense Mutation (SNP) | VAF 80/458 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP42 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 90/377 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- WDR48 | c.491T>C p.L164S | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WTAP | c.53T>G p.F18C | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ZEB2 | c.650_653dup p.G219Pfs*21 | Frame Shift Ins (INS) | VAF 109/421 reads (26%) | called by pindel, varscan2
- ZNF320 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2
- ZNF469 | c.7037G>C p.S2346T (on ENST00000437464; = p.S2374T on NM_001367624.2) | Missense Mutation (SNP) | VAF 127/599 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ZNF735 | c.781A>T p.R261* | Nonsense Mutation (SNP) | VAF 129/526 reads (25%) | called by muse, mutect2, varscan2
- ZNF804B | c.833A>G p.E278G | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF845 | c.143-1G>C p.X48_splice | Splice Site (SNP) | VAF 53/228 reads (23%) | called by muse, mutect2, varscan2
- ACSM4 | c.429G>A p.P143= | Silent (SNP) | VAF 71/398 reads (18%) | catalogued as rs552295510, COSV101257044; called by muse, mutect2, varscan2
- ADAMTS16 | c.2184T>C p.S728= | Silent (SNP) | VAF 74/343 reads (22%) | called by muse, mutect2, varscan2
- ANAPC7 | c.1393T>C p.L465= | Silent (SNP) | VAF 117/633 reads (18%) | called by muse, mutect2, varscan2
- C4orf54 | c.3876G>A p.S1292= | Silent (SNP) | VAF 83/367 reads (23%) | catalogued as COSV72767026; called by muse, mutect2, varscan2
- CAPN5 | c.885C>T p.A295= (on ENST00000456580; = p.A255= on NM_004055.5) | Silent (SNP) | VAF 102/848 reads (12%) | catalogued as rs901202847; called by muse, varscan2
- CCN2 | c.504G>A p.E168= | Silent (SNP) | VAF 112/531 reads (21%) | called by muse, mutect2, varscan2
- CEL | c.2022G>A p.P674= (on ENST00000673714; = p.P671= on NM_001807.6) | Silent (SNP) | VAF 24/218 reads (11%) | catalogued as rs771977099; called by muse, varscan2
- CLEC6A | c.405T>G p.S135= | Silent (SNP) | VAF 70/364 reads (19%) | catalogued as COSV101165725; called by muse, mutect2, varscan2
- DNAH9 | c.552T>C p.T184= | Silent (SNP) | VAF 138/719 reads (19%) | catalogued as COSV52342791; called by muse, mutect2, varscan2
- DNHD1 | c.6283C>T p.L2095= | Silent (SNP) | VAF 160/511 reads (31%) | catalogued as rs924361179; called by muse, mutect2, varscan2
- ERI1 | c.472T>C p.L158= | Silent (SNP) | VAF 34/316 reads (11%) | called by muse, mutect2, varscan2
- FER1L5 | c.5850C>T p.I1950= (on ENST00000623019; = p.I1914= on NM_001293083.2) | Silent (SNP) | VAF 72/588 reads (12%) | called by muse, mutect2, varscan2
- FLG | c.7593G>C p.G2531= | Silent (SNP) | VAF 204/566 reads (36%) | called by mutect2, varscan2
- FOXD4L4 | c.195C>T p.G65= | Silent (SNP) | VAF 90/2429 reads (4%) | called by muse, mutect2
- FOXD4L5 | c.195C>T p.G65= | Silent (SNP) | VAF 66/772 reads (9%) | called by muse, mutect2
- GABRG2 | c.375T>G p.R125= | Silent (SNP) | VAF 52/289 reads (18%) | called by muse, mutect2, varscan2
- GALNT18 | c.708C>T p.V236= | Silent (SNP) | VAF 197/583 reads (34%) | called by muse, mutect2, varscan2
- GK2 | c.21A>G p.A7= | Silent (SNP) | VAF 45/315 reads (14%) | called by muse, mutect2, varscan2
- IGHA2 | c.219G>A p.P73= | Silent (SNP) | VAF 130/756 reads (17%) | catalogued as rs781958889; called by muse, mutect2, varscan2
- INTS3 | c.1356G>A p.V452= | Silent (SNP) | VAF 160/768 reads (21%) | called by muse, mutect2, varscan2
- IRAG2 | c.2910G>C p.V970= (on ENST00000636465; = p.V15= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 83/549 reads (15%) | called by muse, mutect2, varscan2
- ITGA2B | c.1995G>A p.Q665= | Silent (SNP) | VAF 104/554 reads (19%) | catalogued as rs1414830384; called by muse, mutect2, varscan2
- ITM2B | c.747C>T p.F249= | Silent (SNP) | VAF 82/314 reads (26%) | catalogued as rs765077508, COSV66034801; called by muse, mutect2, varscan2
- LCE2C | c.291T>A p.S97= | Silent (SNP) | VAF 95/695 reads (14%) | called by muse, mutect2, varscan2
- LRRC8D | c.1965C>T p.F655= | Silent (SNP) | VAF 81/409 reads (20%) | called by muse, varscan2
- MAGEB5 | c.289T>C p.L97= | Silent (SNP) | VAF 10/300 reads (3%) | catalogued as COSV66868829; called by muse, mutect2
- MAP6 | c.579G>A p.A193= | Silent (SNP) | VAF 31/868 reads (4%) | called by muse, mutect2
- MYH4 | c.3483T>G p.T1161= | Silent (SNP) | VAF 110/596 reads (18%) | catalogued as COSV55127929; called by muse, mutect2, varscan2
- NAV1 | c.564G>A p.A188= | Silent (SNP) | VAF 138/757 reads (18%) | called by muse, mutect2, varscan2
- NCOR2 | c.5964C>T p.H1988= | Silent (SNP) | VAF 114/786 reads (15%) | catalogued as rs747593604; called by muse, varscan2
- NPAP1 | c.102G>A p.P34= | Silent (SNP) | VAF 249/656 reads (38%) | catalogued as COSV100274813; called by muse, mutect2, varscan2
- NPR3 | c.1602C>A p.I534= (on ENST00000265074 / NM_001364458.2; = p.I533= on NM_000908.4) | Silent (SNP) | VAF 49/467 reads (10%) | catalogued as COSV54092258; called by mutect2, varscan2
- OR10A3 | c.510C>A p.G170= | Silent (SNP) | VAF 87/524 reads (17%) | called by muse, mutect2, varscan2
- OR4C16 | c.739T>C p.L247= | Silent (SNP) | VAF 92/565 reads (16%) | catalogued as rs756231148, COSV100114128, COSV58940642; called by muse, mutect2, varscan2
- OR5H14 | c.39T>A p.V13= | Silent (SNP) | VAF 64/405 reads (16%) | called by muse, mutect2, varscan2
- OR5K4 | c.804T>C p.D268= | Silent (SNP) | VAF 38/196 reads (19%) | called by muse, mutect2, varscan2
- OR6X1 | c.183T>A p.L61= | Silent (SNP) | VAF 20/659 reads (3%) | catalogued as COSV60010134; called by muse, mutect2
- PACS2 | c.261A>G p.Q87= | Silent (SNP) | VAF 103/489 reads (21%) | catalogued as COSV57651615, COSV57655980; called by muse, mutect2, varscan2
- PCDH10 | c.834C>T p.D278= | Silent (SNP) | VAF 109/607 reads (18%) | catalogued as rs149439832; called by muse, mutect2, varscan2
- PCDHGB2 | c.1392C>T p.N464= | Silent (SNP) | VAF 115/514 reads (22%) | catalogued as COSV53946631; called by muse, mutect2, varscan2
- PCLO | c.7617T>G p.T2539= | Silent (SNP) | VAF 120/512 reads (23%) | catalogued as COSV61654290; called by muse, mutect2, varscan2
- PLEKHA3 | c.36C>T p.L12= | Silent (SNP) | VAF 50/430 reads (12%) | catalogued as rs146439609; called by muse, mutect2, varscan2
- PRRT4 | c.2037G>A p.A679= | Silent (SNP) | VAF 202/749 reads (27%) | called by muse, mutect2, varscan2
- PRSS8 | c.585G>A p.L195= | Silent (SNP) | VAF 94/612 reads (15%) | called by muse, varscan2
- PTGIR | c.1044T>G p.P348= | Silent (SNP) | VAF 96/512 reads (19%) | called by mutect2, varscan2
- RASAL1 | c.1422C>T p.F474= | Silent (SNP) | VAF 18/621 reads (3%) | catalogued as rs1360685454; called by muse, mutect2
- RELA | c.1318C>T p.L440= | Silent (SNP) | VAF 135/770 reads (18%) | catalogued as rs1230656083; called by muse, mutect2, varscan2
- RYR3 | c.13149G>T p.P4383= (on ENST00000389232; = p.P4384= on NM_001036.6) | Silent (SNP) | VAF 102/452 reads (23%) | catalogued as COSV66792148; called by muse, mutect2, varscan2
- S1PR1 | c.732C>A p.A244= | Silent (SNP) | VAF 116/643 reads (18%) | called by muse, mutect2, varscan2
- SCN4B | c.633G>A p.T211= | Silent (SNP) | VAF 192/541 reads (35%) | catalogued as rs111905160, COSV61252675; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN7A | c.2121T>G p.P707= | Silent (SNP) | VAF 171/654 reads (26%) | catalogued as COSV69270879; called by muse, mutect2, varscan2
- SEMA3D | c.1752C>T p.C584= | Silent (SNP) | VAF 14/380 reads (4%) | called by muse, mutect2
- SLC25A48 | c.339C>T p.A113= | Silent (SNP) | VAF 123/599 reads (21%) | catalogued as rs552013288, COSV50848094; called by muse, mutect2, varscan2
- SLC26A7 | c.1002C>T p.F334= | Silent (SNP) | VAF 53/531 reads (10%) | catalogued as rs774614290; called by muse, mutect2, varscan2
- SYCP2 | c.1518A>T p.R506= | Silent (SNP) | VAF 56/376 reads (15%) | called by muse, mutect2, varscan2
- TMTC1 | c.30C>T p.G10= | Silent (SNP) | VAF 47/412 reads (11%) | catalogued as rs1226175028; called by muse, mutect2, varscan2
- TTN | c.76162A>C p.R25388= (on ENST00000591111; = p.R17964= on NM_003319.4) | Silent (SNP) | VAF 99/567 reads (17%) | catalogued as COSV59955645; called by muse, mutect2, varscan2
- UQCRHL | c.243C>T p.C81= | Silent (SNP) | VAF 125/584 reads (21%) | catalogued as rs376489865; called by muse, mutect2, varscan2
- USP18 | c.789T>C p.N263= | Silent (SNP) | VAF 50/291 reads (17%) | called by muse, mutect2, varscan2
- VPS50 | c.1615T>C p.L539= | Silent (SNP) | VAF 42/288 reads (15%) | called by muse, mutect2, varscan2
- VSTM2A | c.660A>C p.G220= | Silent (SNP) | VAF 104/533 reads (20%) | called by muse, mutect2, varscan2
- WDR7 | c.459A>G p.V153= | Silent (SNP) | VAF 13/291 reads (4%) | called by muse, mutect2
- WDR87 | c.2610G>A p.L870= | Silent (SNP) | VAF 201/398 reads (51%) | called by muse, mutect2, varscan2
- WSCD2 | c.229C>A p.R77= | Silent (SNP) | VAF 221/650 reads (34%) | catalogued as COSV54589936; called by muse, mutect2, varscan2
- XIRP2 | c.711T>G p.T237= (on ENST00000628543; = p.T412= on NM_152381.6) | Silent (SNP) | VAF 177/577 reads (31%) | called by muse, mutect2, varscan2
- ZNF257 | c.651T>G p.T217= | Silent (SNP) | VAF 65/309 reads (21%) | called by muse, mutect2, varscan2
- CR1 | c.487+11964T>A | Intron (SNP) | VAF 82/517 reads (16%) | catalogued as COSV65464984; called by muse, mutect2, varscan2
- DCHS2 | n.2700A>C | RNA (SNP) | VAF 62/300 reads (21%) | catalogued as COSV100252393; called by muse, mutect2, varscan2
- RIMS2 | c.1692+212T>G | Intron (SNP) | VAF 111/827 reads (13%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-48014A>C | Intron (SNP) | VAF 36/261 reads (14%) | catalogued as COSV67442844; called by muse, mutect2, varscan2
- XIRP2 | c.*1224A>C | 3'UTR (SNP) | VAF 60/404 reads (15%) | catalogued as rs1241496256; called by muse, mutect2, varscan2
- ZNF276 | c.-1C>T | 5'UTR (SNP) | VAF 16/464 reads (3%) | called by muse, mutect2
